Gene-level copy-number profile of tumor specimen TCGA-BA-4075-01A from TCGA case TCGA-BA-4075, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 49.1 years (17,951 days).
Specimen TCGA-BA-4075-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.9e1f8679-015c-410f-b7bf-a7a5eec6cd76.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BA-4075-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/11539746-3c13-4abc-838b-09a879df3c97

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 3,234; copy number 2: 31,667; copy number 3: 14,827; copy number 4: 5,857; copy number 5: 2,223; copy number 6: 376; copy number 7: 356; copy number 8: 1,096; copy number 9: 16; copy number 12: 12; copy number 13: 84; copy number 15: 17; copy number 17: 3; copy number 24: 12; copy number 49: 27.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-BA-4075-01): tumor purity 0.67, ploidy 2.78, whole-genome doublings 1 (call status: legacy_maf_call).

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:12,297,197–12,297,323, 1 gene: AC092365.1.
- chr21:29,194,071–29,630,751, 1 gene (within-gene range 0–2): BACH1.
- chr21:29,351,634–29,500,386, 5 genes: BACH1-IT1, AP000240.1, BACH1-AS1, BACH1-IT2, BACH1-IT3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4,222 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:189,560,590–191,741,097, 43 genes, copy number 5–15: SLC40A1, AC012488.1, ASNSD1, ASDURF, AC012488.2, ANKAR, OSGEPL1, OSGEPL1-AS1, AC013468.1, ORMDL1, PMS1, C2orf88, TERF1P6, HNRNPCP2, RNF11P1, MSTN, HIBCH, INPP1, MFSD6, AC093388.1, NEMP2, AC108047.1, RN7SKP179, AC006460.2, NAB1, AC006460.1, AC005540.1, GLS, STAT1, RAB1AP1, AC067945.1, AC067945.2, STAT4, AC067945.3, RNU6-959P, AC079777.1, HMGB1P27, AC092614.1, MYO1B, RNU6-1045P, NABP1, AC114778.1, NABP1-OT1.
- chr5:58,198–45,895,970, 710 genes, copy number 6–7 (broad region; genes not listed).
- chr6:62,547,427–65,707,226, 23 genes, copy number 5–6 (within-gene range 3–6): AL355375.1, AL355375.2, AL450346.1, FKBP1C, SPTLC1P3, AL450346.2, LGSN, AL121949.3, AL121949.2, AL121949.1, EEF1B2P5, PTP4A1, RPL7AP34, AL135905.1, AL135905.2, AL513043.1, RPL9P18, PHF3, EYS, AL354719.1, SCAT8, GCNT1P4, AL357375.1.
- chr6:65,788,417–69,389,506, 22 genes, copy number 5–9 (within-gene range 2–9): SLC25A51P1, ADH5P4, NUFIP1P1, AL450336.1, RNU7-66P, AL591004.1, AL365503.1, RNA5SP208, RNU6-280P, Y_RNA, AL713998.1, AL713998.3, AL713998.4, AL713998.2, AL646090.2, AL646090.1, AL593844.1, LINC02549, AL606923.2, AL606923.1, AL391807.1, ADGRB3.
- chr7:70,972–63,263,456, 1,091 genes, copy number 8–12 (broad region; genes not listed).
- chr8:35,862,123–43,674,591, 188 genes, copy number 5 (broad region; genes not listed).
- chr9:137,582,081–138,203,325, 16 genes, copy number 5: ZMYND19, ARRDC1, AL590627.2, ARRDC1-AS1, EHMT1, Metazoa_SRP, SETP5, AL590627.1, MIR602, AL772363.1, CACNA1B, AL591424.1, IL9RP1, TUBBP5, AL591424.2, AL954642.1.
- chr11:69,641,156–70,015,815, 9 genes, copy number 15 (within-gene range 3–15): CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2.
- chr11:70,078,302–72,290,688, 83 genes, copy number 13 (broad region; genes not listed).
- chr11:72,302,139–72,302,965, 1 gene, copy number 13: AP000593.3.
- chr11:98,676,391–102,727,050, 41 genes, copy number 17–49: AP003715.1, AP002428.1, CNTN5, RN7SKP53, RPA2P3, RN7SL222P, PPIAP43, ARHGAP42-AS1, ARHGAP42, RN7SKP115, PGR, PGR-AS1, AP001533.1, TRPC6, MIR3920, AP003080.1, AP000776.1, ANGPTL5, CEP126, CFAP300, RNA5SP535, AP001527.1, AP001527.2, YAP1, AP000942.2, AP000942.1, AP000942.3, AP000942.4, RNU6-952P, AP000942.5, BIRC3, BIRC2, TMEM123, AP001830.1, AP001830.2, MMP7, MMP20, AP000851.1, AP000851.2, MMP27, MMP8.
- chr11:102,751,070–102,754,943, 1 gene, copy number 49 (within-gene range 4–49): AP000619.1.
- chr14:31,291,788–106,875,071, 1,736 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr20:55,997,357–64,313,132, 258 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 813. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
